Somatic mutation profile of tumor specimen TCGA-67-3771-01A (aliquot TCGA-67-3771-01A-01W-0928-08) from TCGA case TCGA-67-3771, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.8 years (28,406 days).
Specimen TCGA-67-3771-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88ecd81d-a882-4adb-ad2c-e75549745b4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-67-3771-10A (Blood Derived Normal), aliquot TCGA-67-3771-10A-01D-1040-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebe634ff-b960-4474-8c6c-1451ad866f6b

The open-access MAF lists 1,226 somatic variants for this specimen: 924 protein-altering or splice-affecting, 271 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 780, Silent 271, Nonsense Mutation 72, Frame Shift Del 36, Splice Site 21, RNA 12, Intron 10, Splice Region 7, 5'Flank 5, Frame Shift Ins 4, In Frame Del 3, 5'UTR 2.

Variants (750 of 1,226; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as rs61748538, CM015069, COSV64671902, COSV64673084; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 23/75 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 5/9 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50262762, COSV50266035; called by muse, mutect2, varscan2
- MAP2K4 | c.891+1G>C p.X297_splice | Splice Site (SNP) | VAF 114/331 reads (34%) | hotspot (GDC flag); catalogued as COSV62255661, COSV62258008, COSV62258724; called by muse, mutect2, varscan2
- TP53 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 33/99 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA9 | c.2918T>A p.I973K | Missense Mutation (SNP) | VAF 80/475 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs1402042205, COSV60622167; called by muse, mutect2, varscan2
- ABCC3 | c.4093C>G p.Q1365E | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV53318685, COSV53326417; called by muse, mutect2, varscan2
- ABCC4 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 28/406 reads (7%) | catalogued as COSV65310647; called by muse, mutect2
- ABCC9 | c.3650G>C p.R1217T | Missense Mutation (SNP) | VAF 143/551 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs12298510, COSV53965202; called by muse, mutect2, varscan2
- ABCC9 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV53965219; called by muse, mutect2, varscan2
- ABCG1 | c.43C>G p.P15A | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV68251368; called by muse, mutect2, varscan2
- ABHD2 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 90/1021 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs377248748; called by muse, mutect2
- ABL2 | c.2679G>C p.K893N (on ENST00000502732 / NM_007314.4; = p.K878N on NM_005158.5) | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); catalogued as COSV61011947; called by muse, mutect2, varscan2
- ACADM | c.931A>T p.K311* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | catalogued as COSV63719942; called by muse, mutect2, varscan2
- ACBD3 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 15/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64729824; called by muse, mutect2
- ACOX3 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV62711258; called by muse, mutect2, varscan2
- ACP5 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54535982; called by muse, mutect2, varscan2
- ACP5 | c.352T>A p.S118T | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.134); catalogued as COSV99520424; called by muse, mutect2, varscan2
- ACSM2A | c.944A>C p.Y315S (on ENST00000219054; = p.Y236S on NM_001308169.2) | Missense Mutation (SNP) | VAF 79/400 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54583158; called by muse, mutect2, varscan2
- ACSS3 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54087059; called by muse, mutect2, varscan2
- ACTR8 | c.1055A>G p.H352R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51635538; called by muse, mutect2, varscan2
- ADAM10 | c.530C>G p.S177* | Nonsense Mutation (SNP) | VAF 65/366 reads (18%) | catalogued as COSV53049939; called by muse, mutect2, varscan2
- ADAM12 | c.1082A>T p.D361V | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100900107, COSV64103821; called by muse, mutect2, varscan2
- ADAM17 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV60397996, COSV60398180; called by muse, mutect2, varscan2
- ADAM29 | c.1736T>G p.I579R | Missense Mutation (SNP) | VAF 42/946 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV100822152; called by muse, mutect2
- ADAM7 | c.2143G>T p.G715* | Nonsense Mutation (SNP) | VAF 97/285 reads (34%) | catalogued as COSV51536680, COSV51546498; called by muse, mutect2, varscan2
- ADAMTS12 | c.4634C>T p.S1545L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV61257937; called by muse, mutect2, varscan2
- ADAMTS12 | c.2668G>T p.E890* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | catalogued as COSV61257941; called by muse, mutect2, varscan2
- ADAMTS17 | c.869G>C p.R290P | Missense Mutation (SNP) | VAF 68/412 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.941); catalogued as COSV51475361; called by muse, mutect2, varscan2
- ADCY10 | c.1765G>C p.D589H | Missense Mutation (SNP) | VAF 102/814 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV63239149; called by muse, mutect2, varscan2
- ADGRB3 | c.2161C>G p.P721A | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs1242236635, COSV65383789, COSV65387777; called by muse, mutect2, varscan2
- ADGRF4 | c.1933-1G>T p.X645_splice | Splice Site (SNP) | VAF 40/62 reads (65%) | catalogued as COSV51949947, COSV51950407; called by muse, mutect2, varscan2
- ADNP2 | c.1451C>G p.S484* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV51537120; called by muse, mutect2, varscan2
- ADRA2A | c.393C>G p.F131L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54527171; called by mutect2, varscan2
- ADRB3 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as COSV61461607; called by muse, mutect2, varscan2
- AEBP1 | c.1295C>A p.A432E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56256190, COSV56260647; called by mutect2, varscan2
- AHCTF1 | c.1087G>A p.E363K (on ENST00000366508; = p.E337K on NM_015446.5) | Missense Mutation (SNP) | VAF 64/348 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as COSV58247297; called by muse, mutect2, varscan2
- AHCYL1 | c.144G>A p.M48I | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); catalogued as COSV63208376; called by muse, mutect2, varscan2
- AHNAK2 | c.2641C>A p.L881I | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs1405225809, COSV100317064, COSV60910570, COSV60915598; called by muse, mutect2, varscan2
- ALG13 | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV52635055; called by muse, mutect2, varscan2
- ALLC | c.135G>A p.W45* | Nonsense Mutation (SNP) | VAF 67/155 reads (43%) | catalogued as COSV52993554; called by muse, mutect2, varscan2
- AMY2B | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63714412; called by muse, mutect2, varscan2
- ANGPT1 | c.920T>C p.M307T | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV52434035; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6529G>T p.V2177L | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.057); catalogued as COSV51842683; called by muse, mutect2, varscan2
- ANKMY1 | c.2425G>T p.E809* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as COSV56031329; called by muse, mutect2, varscan2
- ANKRD29 | c.416A>G p.H139R | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52424852; called by muse, mutect2, varscan2
- ANKRD34B | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV58613595; called by muse, varscan2
- ANKRD52 | c.851A>T p.N284I | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV57283175, COSV99031712; called by muse, varscan2
- ANKRD55 | c.1138G>T p.D380Y | Missense Mutation (SNP) | VAF 131/742 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV61944945; called by muse, mutect2, varscan2
- ANKZF1 | c.652G>C p.A218P | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55475792; called by muse, mutect2, varscan2
- ANO5 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 152/458 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61083227; called by muse, mutect2, varscan2
- APEH | c.2187C>G p.H729Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV56532663; called by muse, mutect2, varscan2
- APOA4 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as rs1352011550, COSV63360187; called by muse, mutect2, varscan2
- APOA5 | c.551C>A p.T184N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as CM1213290, COSV57062636; called by muse, mutect2, varscan2
- APOB | c.4726G>T p.G1576W | Missense Mutation (SNP) | VAF 85/180 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51927827; called by muse, varscan2
- ARHGAP12 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 101/463 reads (22%) | catalogued as COSV60962116; called by muse, mutect2, varscan2
- ARHGAP28 | c.1358G>T p.R453I (on ENST00000383472 / NM_001366230.1; = p.R294I on NM_001010000.3) | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV51633777; called by muse, mutect2
- ARHGEF37 | c.1147A>T p.S383C | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61368214; called by muse, mutect2, varscan2
- ARID1A | c.3219del p.W1073Cfs*20 | Frame Shift Del (DEL) | VAF 44/121 reads (36%) | catalogued as COSV104411790; called by mutect2, pindel, varscan2
- ARMT1 | c.778G>T p.V260F | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV66178428; called by muse, mutect2, varscan2
- ARPP21 | c.1609C>A p.P537T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV51793997; called by muse, mutect2, varscan2
- ARRDC1 | c.452C>G p.S151C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as rs767794828, COSV58372060; called by muse, mutect2, varscan2
- ASB8 | c.543C>A p.N181K | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56656437; called by muse, mutect2, varscan2
- ASB9 | c.536A>G p.Q179R | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV66851438; called by muse, mutect2, varscan2
- ASPM | c.8735G>C p.S2912T | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV54126609; called by muse, mutect2
- ASTN1 | c.3470C>A p.A1157E | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62493477; called by muse, mutect2, varscan2
- ASTN1 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 58/425 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.127); catalogued as COSV56064290; called by muse, mutect2, varscan2
- ASXL1 | c.404C>A p.S135Y | Missense Mutation (SNP) | VAF 45/590 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60104996, COSV60118368; called by muse, mutect2
- ATG101 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as rs1199689526, COSV61085000; called by muse, mutect2, varscan2
- ATP4A | c.339C>A p.C113* | Nonsense Mutation (SNP) | VAF 36/103 reads (35%) | catalogued as rs761748330, COSV52866616; called by muse, mutect2, varscan2
- ATP6V1H | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV62217452; called by muse, mutect2, varscan2
- ATP7B | c.3919G>T p.V1307L | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54436306; called by muse, mutect2, varscan2
- ATP8A2 | c.2041G>T p.D681Y | Missense Mutation (SNP) | VAF 128/442 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54942662; called by muse, mutect2, varscan2
- ATRN | c.1392C>G p.I464M | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV53525082; called by muse, mutect2, varscan2
- ATRNL1 | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 63/322 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.089); catalogued as rs782432237, COSV61799560; called by muse, mutect2, varscan2
- ATXN7L2 | c.700+1G>A p.X234_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as rs1288347363, COSV63992122; called by muse, mutect2, varscan2
- AURKC | c.442G>T p.E148* (on ENST00000302804 / NM_001015878.2; = p.E114* on NM_003160.3) | Nonsense Mutation (SNP) | VAF 16/104 reads (15%) | catalogued as COSV100248927, COSV57140611; called by muse, mutect2, varscan2
- AVPR1A | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as COSV54545893; called by muse, mutect2, varscan2
- BACH2 | c.2330C>A p.P777H | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as COSV57587339; called by muse, mutect2, varscan2
- BCAN | c.1033C>T p.H345Y | Missense Mutation (SNP) | VAF 150/286 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs1228691023, COSV61255872; called by muse, mutect2, varscan2
- BCAS3 | c.215-1G>A p.X72_splice | Splice Site (SNP) | VAF 42/115 reads (37%) | catalogued as COSV66771142; called by muse, mutect2, varscan2
- BCL11A | c.1895C>G p.S632C (on ENST00000335712 / NM_001365609.1; = p.S666C on NM_018014.4) | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59626246; called by muse, mutect2, varscan2
- BDP1 | c.3334G>A p.G1112S | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.031); catalogued as COSV62429784; called by muse, mutect2, varscan2
- BHMT | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57153799, COSV57155603; called by muse, mutect2, varscan2
- BICC1 | c.2341G>T p.V781L | Missense Mutation (SNP) | VAF 115/328 reads (35%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.672); catalogued as COSV54062591; called by muse, mutect2, varscan2
- BLOC1S2 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100705076; called by muse, mutect2, varscan2
- BMS1 | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 165/1024 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV65733166; called by muse, mutect2, varscan2
- BRINP3 | c.2297G>T p.S766I | Missense Mutation (SNP) | VAF 72/580 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); catalogued as COSV100819385, COSV66516757; called by muse, varscan2
- BRINP3 | c.1270C>A p.H424N | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV66516763; called by muse, mutect2, varscan2
- BRS3 | c.44C>G p.S15* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV65710780, COSV65711206; called by muse, mutect2, varscan2
- BSN | c.3556G>T p.E1186* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as COSV56514545; called by muse, mutect2, varscan2
- BUB1 | c.668C>G p.S223* | Nonsense Mutation (SNP) | VAF 22/129 reads (17%) | catalogued as COSV57061958; called by muse, mutect2, varscan2
- C20orf194 | c.2592G>A p.M864I | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV52693024; called by muse, mutect2, varscan2
- C2orf16 | c.1033G>C p.D345H | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.639); catalogued as COSV68645541; called by muse, mutect2, varscan2
- C2orf16 | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.774); catalogued as COSV68645545, COSV68645863; called by muse, mutect2, varscan2
- C3orf70 | c.509C>G p.S170* | Nonsense Mutation (SNP) | VAF 100/331 reads (30%) | catalogued as COSV58586905; called by muse, mutect2, varscan2
- C6 | c.2605G>T p.D869Y | Missense Mutation (SNP) | VAF 300/1068 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs115220610, COSV54707056; called by mutect2, varscan2
- C6 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 58/360 reads (16%) | catalogued as COSV54707063; called by muse, mutect2, varscan2
- CABP1 | c.983G>A p.R328Q (on ENST00000316803 / NM_001033677.1; = p.R125Q on NM_004276.5) | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.445); catalogued as rs866526568, COSV56457899, COSV56459072; called by muse, mutect2, varscan2
- CACNG2 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 142/376 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV55633281; called by muse, mutect2, varscan2
- CAMKK1 | c.623A>T p.H208L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50114647; called by muse, mutect2, varscan2
- CAMKV | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.969); catalogued as COSV56554485; called by muse, mutect2, varscan2
- CAMTA1 | c.4438A>G p.S1480G | Missense Mutation (SNP) | VAF 45/364 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV57887322; called by muse, mutect2, varscan2
- CAPN11 | c.964T>A p.W322R | Missense Mutation (SNP) | VAF 121/244 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67236736; called by muse, mutect2, varscan2
- CAPN9 | c.953+2T>A p.X318_splice | Splice Site (SNP) | VAF 30/272 reads (11%) | catalogued as COSV55231627; called by muse, mutect2, varscan2
- CASQ1 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 176/316 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as COSV63623979; called by muse, mutect2, varscan2
- CATSPERE | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 330/821 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV63676758; called by muse, mutect2, varscan2
- CBL | c.2680G>T p.E894* | Nonsense Mutation (SNP) | VAF 266/790 reads (34%) | catalogued as COSV50631635, COSV50677442; called by mutect2, varscan2
- CCDC6 | c.1180A>T p.N394Y | Missense Mutation (SNP) | VAF 124/315 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as COSV54055495; called by muse, mutect2, varscan2
- CCDC87 | c.2510A>T p.H837L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV59578604; called by muse, mutect2, varscan2
- CCND1 | c.74A>C p.D25A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV57119875; called by muse, mutect2, varscan2
- CCR2 | c.1076C>A p.S359* | Nonsense Mutation (SNP) | VAF 60/292 reads (21%) | catalogued as COSV52747969; called by muse, mutect2, varscan2
- CD300A | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV60409696; called by muse, mutect2, varscan2
- CD33 | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV51800539; called by muse, mutect2, varscan2
- CD33 | c.928C>A p.H310N | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV51800558; called by muse, mutect2, varscan2
- CD5 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.399); catalogued as COSV61718028; called by muse, mutect2, varscan2
- CD83 | c.178A>T p.M60L | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64787648; called by muse, mutect2, varscan2
- CD99L2 | c.68-1G>T p.X23_splice | Splice Site (SNP) | VAF 23/93 reads (25%) | catalogued as COSV57986695; called by muse, mutect2, varscan2
- CDCA7L | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs201734057, COSV62258479; called by muse, mutect2, varscan2
- CDH10 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV52574133; called by muse, mutect2, varscan2
- CDH12 | c.1518A>G p.I506M | Missense Mutation (SNP) | VAF 82/387 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV66393601; called by muse, mutect2, varscan2
- CDH2 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52274334; called by muse, mutect2, varscan2
- CDK13 | c.4078G>C p.A1360P | Missense Mutation (SNP) | VAF 82/346 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.502); catalogued as rs1288031998, COSV51697493; called by muse, mutect2, varscan2
- CDKN2A | c.155T>G p.M52R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV58688565, COSV58689863, COSV58725322; called by muse, mutect2, varscan2
- CDYL | c.652G>T p.E218* (on ENST00000328908 / NM_001368125.1; = p.E164* on NM_004824.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as COSV59358767; called by muse, mutect2, varscan2
- CENPE | c.4270C>G p.L1424V | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.76); catalogued as COSV54377949; called by muse, mutect2, varscan2
- CEP152 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.698); catalogued as rs1210137540, COSV100359009; called by muse, mutect2, varscan2
- CEP152 | c.2082A>T p.L694F | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100359010; called by muse, mutect2, varscan2
- CEP170 | c.3623G>T p.R1208L | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60507210; called by muse, mutect2, varscan2
- CFAP251 | c.1852C>T p.Q618* | Nonsense Mutation (SNP) | VAF 153/581 reads (26%) | catalogued as COSV56608924; called by muse, mutect2, varscan2
- CFAP70 | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60281722; called by muse, mutect2, varscan2
- CFDP1 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV52207911; called by muse, mutect2, varscan2
- CFHR2 | c.731G>C p.G244A | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.779); catalogued as COSV66380704, COSV66380788; called by muse, mutect2, varscan2
- CHD6 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV58554239; called by muse, mutect2, varscan2
- CHD7 | c.5410G>T p.E1804* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as COSV71107832; called by muse, mutect2
- CHD8 | c.6769G>C p.D2257H (on ENST00000646647 / NM_001170629.2; = p.D1978H on NM_020920.4) | Missense Mutation (SNP) | VAF 125/490 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV63036576; called by muse, mutect2, varscan2
- CHMP4B | c.223T>C p.Y75H | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as COSV99459921; called by muse, mutect2, varscan2
- CHRD | c.1448G>C p.G483A | Missense Mutation (SNP) | VAF 91/330 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52606248, COSV99200426; called by muse, mutect2, varscan2
- CHRNA1 | c.1037G>T p.R346L (on ENST00000261007 / NM_001039523.3; = p.R321L on NM_000079.4) | Missense Mutation (SNP) | VAF 101/201 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV53682061, COSV53683259; called by muse, mutect2, varscan2
- CLEC16A | c.1633A>G p.R545G | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs757795232, COSV68498540; called by muse, mutect2, varscan2
- CLEC4F | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 97/173 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV55478593; called by muse, mutect2, varscan2
- CLK4 | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60317999; called by muse, mutect2, varscan2
- CLN3 | c.960C>A p.F320L (on ENST00000360019 / NM_001286104.2; = p.F344L on NM_000086.2) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.079); catalogued as COSV61105120; called by muse, mutect2, varscan2
- CLTCL1 | c.4417G>C p.E1473Q | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV54226713; called by muse, mutect2
- CMPK2 | c.882C>G p.I294M | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV56774177; called by muse, mutect2, varscan2
- CNGA2 | c.1357C>A p.R453S | Missense Mutation (SNP) | VAF 42/345 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as rs755787323, COSV61703700, COSV61705041; called by muse, mutect2, varscan2
- CNIH3 | c.158G>C p.R53P | Missense Mutation (SNP) | VAF 59/405 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs775410636, COSV55272980, COSV55273623; called by muse, mutect2, varscan2
- CNTN1 | c.2227A>G p.I743V | Missense Mutation (SNP) | VAF 100/276 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.074); catalogued as rs759677391, COSV61637404; called by muse, mutect2, varscan2
- COBL | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54340899; called by muse, mutect2, varscan2
- COL11A1 | c.1295C>G p.A432G | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV62176078; called by muse, mutect2, varscan2
- COL14A1 | c.3886C>G p.P1296A | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as COSV52849671, COSV52857235; called by muse, mutect2, varscan2
- COL3A1 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 54/468 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); catalogued as COSV58584162; called by muse, mutect2, varscan2
- COL3A1 | c.2303G>T p.G768V | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58584172; called by muse, mutect2
- COL4A1 | c.4150+2T>A p.X1384_splice | Splice Site (SNP) | VAF 10/80 reads (13%) | catalogued as COSV65422905; called by muse, mutect2, varscan2
- COL4A6 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 149/542 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100564661; called by muse, mutect2, varscan2
- COL4A6 | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 149/538 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV100564662; called by muse, mutect2, varscan2
- COL5A1 | c.2821C>T p.P941S | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs1208939443, COSV65666644; called by muse, mutect2, varscan2
- COL9A1 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 41/306 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV61830105; called by muse, mutect2, varscan2
- COL9A2 | c.421del p.D141Tfs*42 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as COSV65607297; called by mutect2, pindel, varscan2
- COLEC11 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV52592230; called by muse, mutect2, varscan2
- COLQ | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV67524277, COSV67525299; called by muse, mutect2, varscan2
- CORO1C | c.321A>G p.V107= | Splice Region (SNP) | VAF 20/60 reads (33%) | catalogued as COSV54594675; called by muse, mutect2, varscan2
- CPSF2 | c.1043A>T p.D348V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV54097470; called by muse, mutect2, varscan2
- CPXCR1 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as COSV52161514; called by muse, mutect2, varscan2
- CREB5 | c.1078C>T p.Q360* (on ENST00000357727 / NM_182898.4; = p.Q353* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 13/93 reads (14%) | catalogued as COSV63218452, COSV63219666; called by muse, mutect2, varscan2
- CRNKL1 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66105594; called by muse, mutect2, varscan2
- CSF1R | c.2734G>T p.E912* | Nonsense Mutation (SNP) | VAF 27/123 reads (22%) | catalogued as COSV53830990; called by muse, mutect2, varscan2
- CSMD2 | c.8155C>G p.P2719A | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV53890177, COSV53891470, COSV53901887; called by muse, mutect2, varscan2
- CSMD3 | c.7726C>G p.P2576A (on ENST00000297405 / NM_001363185.1; = p.P2472A on NM_052900.3) | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.403); catalogued as COSV52129343; called by muse, mutect2, varscan2
- CSMD3 | c.2281C>G p.L761V (on ENST00000297405 / NM_001363185.1; = p.L657V on NM_052900.3) | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52129362, COSV99828094, COSV99841759; called by muse, mutect2, varscan2
- CSNK1G1 | c.690del p.R231Efs*7 | Frame Shift Del (DEL) | VAF 51/194 reads (26%) | catalogued as COSV100274178; called by mutect2, pindel, varscan2
- CTNNA3 | c.2006A>T p.E669V | Missense Mutation (SNP) | VAF 68/315 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as rs377166040; called by muse, mutect2, varscan2
- CTNND1 | c.1652G>A p.C551Y | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62382565; called by muse, mutect2, varscan2
- CTNND2 | c.2787C>A p.I929= | Splice Region (SNP) | VAF 87/494 reads (18%) | catalogued as COSV58872981; called by muse, mutect2, varscan2
- CUL5 | c.1451G>A p.G484D | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV67608399; called by muse, mutect2, varscan2
- CXCR2 | c.862C>A p.R288S | Missense Mutation (SNP) | VAF 83/157 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.898); catalogued as COSV59280046, COSV59281534; called by muse, mutect2, varscan2
- CXCR4 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as COSV54010898; called by muse, mutect2, varscan2
- CYP1A1 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65696780; called by muse, varscan2
- CYP24A1 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV53773292; called by muse, mutect2, varscan2
- CYP2B6 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 65/414 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs572134005, COSV57842876; called by muse, mutect2, varscan2
- CYP2C18 | c.231G>T p.L77F | Missense Mutation (SNP) | VAF 420/1215 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs755901390, COSV53670548; called by muse, mutect2, varscan2
- CYP2C18 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 140/486 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV53670557; called by muse, mutect2, varscan2
- CYP3A7 | c.970C>A p.H324N | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as COSV60480298, COSV60480876; called by muse, mutect2, varscan2
- CYP4X1 | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as COSV64149986; called by muse, mutect2, varscan2
- DACH1 | c.2005G>T p.A669S (on ENST00000619232 / NM_001366712.1; = p.A415S on NM_004392.6) | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.223); catalogued as rs778355424, COSV57493066; called by muse, mutect2, varscan2
- DACT1 | c.1025T>A p.I342N | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60019860; called by muse, mutect2, varscan2
- DAGLA | c.575C>G p.T192S | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1272458858, COSV57194808; called by muse, mutect2
- DBX2 | c.875G>C p.R292T | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV60336702, COSV60339821; called by muse, mutect2, varscan2
- DCAF1 | c.1936G>C p.V646L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.131); catalogued as COSV60041238, COSV60041463; called by muse, mutect2, varscan2
- DCAF12L2 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 31/119 reads (26%) | catalogued as COSV63580787; called by muse, mutect2, varscan2
- DCAF8 | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 66/135 reads (49%) | catalogued as COSV58783101; called by muse, mutect2, varscan2
- DCDC1 | c.2113A>T p.T705S | Missense Mutation (SNP) | VAF 82/591 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.423); catalogued as COSV60836810; called by muse, mutect2, varscan2
- DDI1 | c.1134G>T p.E378D | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV56371503; called by muse, mutect2, varscan2
- DDIAS | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 165/749 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV61271692; called by muse, mutect2, varscan2
- DDX17 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV53251377, COSV53255915; called by muse, mutect2, varscan2
- DEGS1 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60378802; called by muse, mutect2, varscan2
- DHX37 | c.1304G>T p.R435M | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58132843; called by muse, mutect2, varscan2
- DHX57 | c.1016A>C p.D339A | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.326); catalogued as COSV54883341; called by muse, mutect2, varscan2
- DIS3 | c.2744C>T p.S915L | Missense Mutation (SNP) | VAF 37/332 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as rs754234020, COSV66705903; called by muse, mutect2, varscan2
- DIS3L2 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 174/415 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV56050451; called by muse, mutect2, varscan2
- DLGAP5 | c.2021A>C p.E674A | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as COSV55962504; called by muse, mutect2
- DLGAP5 | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1399159335, COSV55962516; called by muse, mutect2
- DMBT1 | c.4949G>T p.R1650L (on ENST00000338354 / NM_001377530.1; = p.R893L on NM_004406.3) | Missense Mutation (SNP) | VAF 215/1161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775509248, COSV57537673, COSV57538240; called by muse, mutect2, varscan2
- DMRT2 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV52401204; called by muse, mutect2, varscan2
- DNAAF3 | c.1333G>T p.A445S (on ENST00000524407 / NM_001256715.2; = p.A492S on NM_178837.4) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.085); catalogued as rs768592462, COSV61275914; called by muse, mutect2, varscan2
- DNAH11 | c.5501G>A p.R1834H | Missense Mutation (SNP) | VAF 132/1632 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs750430725, COSV60945433; ClinVar: uncertain significance; called by muse, mutect2
- DNAJC6 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 76/373 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54771615; called by muse, mutect2, varscan2
- DNHD1 | c.11593A>T p.S3865C | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV54432134; called by muse, mutect2, varscan2
- DNM3 | c.1897C>G p.P633A (on ENST00000355305 / NM_001350206.2; = p.P623A on NM_015569.5) | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV62454903; called by muse, mutect2, varscan2
- DOCK2 | c.2733C>G p.I911M | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV56947788; called by muse, mutect2, varscan2
- DOCK4 | c.5026A>T p.T1676S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.069); catalogued as COSV70234441; called by muse, mutect2
- DPF3 | c.476A>G p.E159G | Missense Mutation (SNP) | VAF 219/398 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV63499267; called by muse, mutect2, varscan2
- DRC7 | c.191C>G p.S64* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV61053663; called by muse, mutect2, varscan2
- DRD3 | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 388/780 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55679227; called by muse, mutect2, varscan2
- DRD3 | c.134T>A p.F45Y | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55679238; called by muse, mutect2
- DRD5 | c.398T>A p.V133D | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58577168; called by muse, mutect2, varscan2
- DST | c.16051C>G p.Q5351E (on ENST00000361203 / NM_001374722.1; = p.Q2939E on NM_015548.5) | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); catalogued as COSV55003459; called by muse, mutect2, varscan2
- DTNA | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 15/141 reads (11%) | catalogued as COSV51995122, COSV52002591; called by muse, mutect2, varscan2
- DYNC2H1 | c.3652G>A p.G1218R | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.692); catalogued as COSV62089227; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1138G>A p.D380N (on ENST00000361735 / NM_015935.5; = p.D294N on NM_014955.3) | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.553); catalogued as COSV62282670; called by muse, mutect2, varscan2
- EEPD1 | c.1466T>C p.L489P | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.876); catalogued as rs763134888, COSV54196628; called by muse, mutect2, varscan2
- EFCAB13 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 64/378 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58946595; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57515123; called by muse, mutect2
- EIF4G1 | c.3371C>G p.S1124* (on ENST00000346169 / NM_198241.3; = p.S929* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 9/157 reads (6%) | catalogued as COSV59989805; called by muse, mutect2
- EIF5B | c.1350G>C p.K450N | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV56811692; called by muse, mutect2, varscan2
- ELMO2 | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 100/313 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV51681845; called by muse, mutect2, varscan2
- ELN | c.631C>G p.P211A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as CM093575, COSV52708187; called by muse, mutect2, varscan2
- ELOA2 | c.1396T>A p.S466T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV55295144; called by muse, varscan2
- ELP2 | c.1253G>T p.W418L | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV60849461; called by muse, mutect2, varscan2
- EML4 | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 57/313 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100581489, COSV59295170; called by muse, mutect2, varscan2
- ENOX1 | c.699G>T p.R233S | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54891298; called by muse, mutect2, varscan2
- ENTHD1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV57318176; called by muse, mutect2, varscan2
- ENTPD1 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 70/430 reads (16%) | catalogued as COSV64600588; called by muse, mutect2, varscan2
- EPB41L4A | c.1544G>T p.W515L | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV54864692; called by muse, mutect2, varscan2
- EPHA10 | c.1952T>C p.L651P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57621932; called by muse, mutect2, varscan2
- EPHA3 | c.2882C>G p.P961R | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV60698074, COSV60722530; called by muse, mutect2, varscan2
- EPHA5 | c.844T>C p.W282R | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56635862; called by muse, mutect2, varscan2
- EPHA6 | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 573/1078 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV67563797, COSV67593476; called by muse, mutect2, varscan2
- EPHA6 | c.1396T>A p.C466S | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV67563804; called by muse, mutect2, varscan2
- EPHA7 | c.936T>G p.C312W | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65178959; called by muse, mutect2, varscan2
- EPHB1 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1466117759, COSV67656148; called by muse, mutect2, varscan2
- EPHB1 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV67656151; called by muse, varscan2
- EPHB2 | c.128G>T p.W43L | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65860717; called by muse, mutect2, varscan2
- EPYC | c.632C>A p.T211N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV53800216; called by muse, mutect2, varscan2
- ERBB4 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV53512670; called by muse, mutect2, varscan2
- ERCC6 | c.3007G>C p.E1003Q | Missense Mutation (SNP) | VAF 52/352 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63388556; called by muse, mutect2, varscan2
- ERN1 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV70500929; called by muse, mutect2, varscan2
- EXOC7 | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV58740054; called by muse, mutect2, varscan2
- EYA1 | c.1632G>T p.R544S | Missense Mutation (SNP) | VAF 112/395 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV58158917; called by muse, mutect2, varscan2
- EZH2 | c.1490G>A p.R497Q (on ENST00000460911 / NM_001203247.2; = p.R502Q on NM_004456.5) | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1263153853, COSV57448811, COSV99052998; called by muse, mutect2, varscan2
- F8 | c.5488G>A p.E1830K | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); catalogued as COSV64270634; called by muse, mutect2, varscan2
- FADS6 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100043868, COSV100044310; called by muse, varscan2
- FAM13A | c.1906C>A p.P636T | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV51999102; called by muse, mutect2, varscan2
- FAM13C | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53245076; called by muse, mutect2, varscan2
- FAM71A | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 53/445 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV54234966; called by muse, mutect2, varscan2
- FANCM | c.2375C>G p.S792* | Nonsense Mutation (SNP) | VAF 19/167 reads (11%) | catalogued as COSV57498428; called by muse, mutect2, varscan2
- FAT3 | c.6764A>G p.K2255R | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV53088164; called by muse, mutect2
- FBN1 | c.7789C>T p.L2597F | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.996); catalogued as CD1312141, COSV57312065; called by muse, mutect2, varscan2
- FBN1 | c.1534A>C p.T512P | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV57312074; called by muse, mutect2
- FBN2 | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV52499778; called by muse, mutect2, varscan2
- FBXL7 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.06); catalogued as rs548322966, COSV61642962, COSV61648367; called by mutect2, varscan2
- FCGR1A | c.856C>G p.P286A | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as COSV64985389; called by muse, mutect2, varscan2
- FCHO1 | c.2078C>A p.A693D | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as COSV53181389; called by muse, mutect2, varscan2
- FCRL4 | c.1247C>A p.S416* | Nonsense Mutation (SNP) | VAF 77/161 reads (48%) | catalogued as COSV54860767; called by muse, varscan2
- FCRL5 | c.2318G>A p.C773Y | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as COSV62512796; called by muse, mutect2, varscan2
- FGD3 | c.1006A>T p.N336Y | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV61596082; called by muse, mutect2
- FHL1 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 144/726 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV61780171; called by muse, mutect2, varscan2
- FIG4 | c.1886G>A p.R629K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57785826; called by muse, mutect2, varscan2
- FIGNL1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as COSV63553318; called by muse, mutect2, varscan2
- FLACC1 | c.488G>T p.C163F | Missense Mutation (SNP) | VAF 183/367 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV53782685; called by muse, mutect2, varscan2
- FLG | c.5824C>A p.H1942N | Missense Mutation (SNP) | VAF 207/582 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV64238598; called by muse, mutect2, varscan2
- FLG | c.2219G>T p.R740L | Missense Mutation (SNP) | VAF 137/1161 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV100910374, COSV64238603; called by muse, mutect2
- FLNB | c.4388G>C p.R1463P | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV55873516; called by muse, mutect2, varscan2
- FLT1 | c.3752C>A p.A1251D | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs1342649833, COSV56721515; called by muse, mutect2, varscan2
- FLT1 | c.1183G>C p.V395L | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56721532; called by muse, mutect2, varscan2
- FLT3 | c.2957C>A p.P986Q | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.238); catalogued as COSV54047766, COSV54049596; called by muse, mutect2, varscan2
- FMO1 | c.739C>A p.L247I | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV61445023; called by muse, mutect2, varscan2
- FN1 | c.1858C>G p.P620A | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV60548514; called by muse, mutect2, varscan2
- FOLR3 | c.173G>C p.S58T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as COSV61529954; called by muse, mutect2, varscan2
- FOXE3 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM163143, COSV100624042, COSV58632486; called by muse, mutect2
- FPR2 | c.92T>A p.V31E | Missense Mutation (SNP) | VAF 76/384 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV60672229; called by muse, mutect2, varscan2
- FPR2 | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 61/351 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV60672236; called by muse, mutect2, varscan2
- FPR3 | c.145T>A p.W49R | Missense Mutation (SNP) | VAF 302/868 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59328707; called by muse, mutect2, varscan2
- FRAS1 | c.8019A>C p.E2673D | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53597024; called by muse, mutect2, varscan2
- FRMD3 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.65); catalogued as COSV58456649; called by muse, mutect2, varscan2
- FSCN3 | c.512_514del p.A171del | In Frame Del (DEL) | VAF 26/163 reads (16%) | catalogued as rs1226954046; called by pindel, varscan2
- G3BP1 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV62365773; called by muse, mutect2, varscan2
- GABRR1 | c.1007C>G p.P336R | Missense Mutation (SNP) | VAF 326/611 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65619001, COSV65619281; called by muse, mutect2, varscan2
- GAD1 | c.1567A>T p.R523W | Missense Mutation (SNP) | VAF 79/164 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64025215; called by muse, mutect2, varscan2
- GALNT10 | c.1799T>G p.F600C | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV51722100; called by muse, varscan2
- GARS1 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66828055; called by muse, mutect2, varscan2
- GAS2L3 | c.1421T>C p.L474S | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs893113700, COSV57156464; called by muse, mutect2, varscan2
- GGH | c.834A>G p.E278= | Splice Region (SNP) | VAF 25/201 reads (12%) | catalogued as rs778610598, COSV52649627; called by muse, mutect2, varscan2
- GJA5 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 60/472 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54783114, COSV99605717; called by muse, mutect2, varscan2
- GLO1 | c.84G>T p.K28N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV64905071; called by muse, mutect2
- GLYAT | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.964); catalogued as COSV53538273, COSV53538715; called by muse, mutect2, varscan2
- GLYAT | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 50/289 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53538730, COSV99557501; called by muse, mutect2
- GML | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV55276610; called by muse, mutect2, varscan2
- GMPS | c.319A>G p.M107V | Missense Mutation (SNP) | VAF 115/528 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV55808414; called by muse, mutect2, varscan2
- GOLGA1 | c.1735G>T p.E579* | Nonsense Mutation (SNP) | VAF 141/344 reads (41%) | catalogued as COSV63024138, COSV63024143; called by muse, mutect2, varscan2
- GOLGB1 | c.2204A>G p.N735S | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1402761486, COSV61463097; called by muse, mutect2, varscan2
- GPR149 | c.1596G>T p.R532S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67666320; called by muse, mutect2, varscan2
- GPR158 | c.1624A>C p.I542L | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV66266935; called by muse, mutect2, varscan2
- GPR158 | c.2681C>A p.P894Q | Missense Mutation (SNP) | VAF 100/432 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); catalogued as COSV66266938; called by muse, mutect2, varscan2
- GPR39 | c.1283T>A p.L428H | Missense Mutation (SNP) | VAF 89/191 reads (47%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.365); catalogued as COSV61416002; called by muse, mutect2, varscan2
- GPR4 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV100546922, COSV100546982, COSV59916428; called by muse, mutect2, varscan2
- GRIK1 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs368404991; called by muse, mutect2, varscan2
- GRIK3 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100901906, COSV66136884; called by muse, mutect2, varscan2
- GRIN2B | c.3159C>A p.D1053E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.109); catalogued as COSV74205137, COSV74206667; called by muse, mutect2, varscan2
- GRIN3A | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as COSV62451861; called by muse, mutect2, varscan2
- GTPBP1 | c.801G>C p.M267I | Missense Mutation (SNP) | VAF 62/406 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV53283748; called by muse, mutect2, varscan2
- H2AZ2 | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56062148, COSV56062905; called by muse, mutect2, varscan2
- H2BC10 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 93/464 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.251); catalogued as COSV59952767, COSV59953351; called by muse, mutect2, varscan2
- HABP4 | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 104/339 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64514676; called by muse, mutect2, varscan2
- HCK | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs776412545, COSV52941097; called by muse, mutect2, varscan2
- HDC | c.1672C>A p.P558T | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as COSV99984198; called by muse, mutect2, varscan2
- HDC | c.1123C>G p.Q375E | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV51068709; called by muse, mutect2, varscan2
- HDC | c.181A>T p.I61F | Missense Mutation (SNP) | VAF 258/652 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.679); catalogued as COSV51068718; called by muse, mutect2, varscan2
- HELQ | c.2999A>G p.K1000R | Missense Mutation (SNP) | VAF 93/213 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV55024464; called by muse, mutect2, varscan2
- HERC1 | c.10670G>A p.G3557E | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71246696; called by muse, mutect2, varscan2
- HERC2 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55313457; called by muse, mutect2
- HGD | c.1180G>T p.G394C | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV52196674; called by muse, mutect2, varscan2
- HK1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.01); catalogued as COSV64350504; called by muse, mutect2, varscan2
- HK2 | c.1525G>A p.V509I | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.974); catalogued as rs763634644, COSV51873897; called by muse, mutect2, varscan2
- HMCN1 | c.6391C>T p.P2131S | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54885346; called by muse, mutect2
- HNRNPA1 | c.20C>G p.P7R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52935986; called by muse, mutect2, varscan2
- HNRNPLL | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 37/89 reads (42%) | catalogued as COSV55367110; called by muse, mutect2, varscan2
- HOXA1 | c.377G>T p.C126F | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56065578; called by muse, mutect2, varscan2
- HPS5 | c.2400T>A p.N800K (on ENST00000349215 / NM_181507.2; = p.N686K on NM_007216.4) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV61687227; called by muse, mutect2, varscan2
- HPS5 | c.2095G>A p.E699K (on ENST00000349215 / NM_181507.2; = p.E585K on NM_007216.4) | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.092); catalogued as COSV61687231; called by muse, mutect2, varscan2
- HPS5 | c.1663G>A p.E555K (on ENST00000349215 / NM_181507.2; = p.E441K on NM_007216.4) | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV61687238; called by muse, mutect2, varscan2
- HPS5 | c.825-1G>A p.X275_splice (on ENST00000349215 / NM_181507.2; = p.X161_splice on NM_007216.4) | Splice Site (SNP) | VAF 21/208 reads (10%) | catalogued as COSV62538952; called by muse, mutect2
- HRH1 | c.1106C>G p.T369R | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV67955171; called by muse, mutect2
- HRH4 | c.94G>T p.G32* | Nonsense Mutation (SNP) | VAF 74/190 reads (39%) | catalogued as COSV56927621; called by muse, varscan2
- HSPG2 | c.1634A>G p.D545G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV65930100; called by muse, mutect2, varscan2
- IFI16 | c.952G>T p.G318W | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55532197; called by muse, mutect2
- IFT172 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 71/403 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs777168931, COSV53131271; called by muse, mutect2, varscan2
- IGDCC4 | c.3463C>A p.P1155T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.1); catalogued as COSV61535916; called by muse, mutect2, varscan2
- IGF2R | c.6399G>T p.Q2133H | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV63482165; called by muse, mutect2, varscan2
- IGHM | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.737); catalogued as rs369232248; called by muse, mutect2, varscan2
- IGHV5-51 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs782344647; called by muse, mutect2, varscan2
- IGKV1-6 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs779529366; called by muse, mutect2, varscan2
- IHH | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as rs1559178825, COSV55392917; called by muse, mutect2, varscan2
- IKBKB | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 121/332 reads (36%) | catalogued as COSV60596275; called by muse, mutect2, varscan2
- IL1A | c.110A>G p.H37R | Missense Mutation (SNP) | VAF 104/206 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV54519110; called by muse, mutect2, varscan2
- IL2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV56985462; called by muse, mutect2, varscan2
- IL4R | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748811310, COSV50139604; called by muse, mutect2, varscan2
- INMT | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 159/497 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs1334310876, COSV50000512; called by muse, mutect2, varscan2
- INO80B | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs115610738, COSV51968607; called by mutect2, varscan2
- INPP4B | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 86/207 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as COSV53715649, COSV53747965; called by muse, mutect2, varscan2
- INTS5 | c.1523T>C p.V508A | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV57950742; called by muse, mutect2, varscan2
- IRF9 | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60702865; called by muse, mutect2, varscan2
- IRS4 | c.1714_1715insT p.G572Vfs*32 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | catalogued as COSV100929644; called by mutect2, varscan2
- ITGA8 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65226342; called by muse, mutect2, varscan2
- ITGAD | c.1543C>A p.H515N | Missense Mutation (SNP) | VAF 183/616 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV66757152; called by muse, mutect2, varscan2
- ITPR2 | c.7400-1G>C p.X2467_splice | Splice Site (SNP) | VAF 28/126 reads (22%) | catalogued as COSV67266495; called by muse, mutect2, varscan2
- JAK1 | c.1488G>C p.K496N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61088663; called by muse, mutect2, varscan2
- JAM2 | c.878C>A p.T293K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100468918, COSV57256059; called by muse, mutect2, varscan2
- KALRN | c.1865T>A p.L622Q | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53756406; called by muse, mutect2, varscan2
- KALRN | c.7374G>A p.M2458I (on ENST00000360013 / NM_001024660.4; = p.M761I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/494 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.899); catalogued as COSV52252038; called by muse, mutect2, varscan2
- KALRN | c.8227C>T p.L2743F (on ENST00000360013 / NM_001024660.4; = p.L1046F on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV52252055; called by muse, mutect2, varscan2
- KBTBD6 | c.636G>T p.E212D | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs542001637, COSV65271033; called by muse, mutect2, varscan2
- KBTBD7 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV65266165; called by muse, mutect2
- KCNA2 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60369435; called by muse, mutect2, varscan2
- KCNB2 | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 87/566 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV73049374, COSV73050465; called by muse, mutect2, varscan2
- KCNJ6 | c.594G>T p.K198N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as COSV55710847; called by muse, mutect2, varscan2
- KCNN1 | c.808A>T p.T270S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV55836962, COSV55837615, COSV55838227; called by muse, mutect2, varscan2
- KCNS3 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV58405863; called by muse, mutect2, varscan2
- KCNU1 | c.1024G>T p.V342L | Missense Mutation (SNP) | VAF 171/444 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.211); catalogued as COSV67754125; called by muse, mutect2, varscan2
- KCNV1 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV52085116; called by mutect2, varscan2
- KHDRBS1 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV56981415; called by muse, mutect2, varscan2
- KHNYN | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.607); catalogued as COSV52159230; called by muse, mutect2, varscan2
- KIAA1549L | c.1707T>A p.D569E (on ENST00000321505; = p.D866E on NM_012194.3) | Missense Mutation (SNP) | VAF 48/229 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.012); catalogued as rs767994861, COSV55770912; called by muse, mutect2, varscan2
- KIAA1755 | c.332C>A p.P111H | Missense Mutation (SNP) | VAF 58/411 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99642397; called by muse, mutect2, varscan2
- KIDINS220 | c.3457G>C p.G1153R | Missense Mutation (SNP) | VAF 121/196 reads (62%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV56751374; called by muse, mutect2, varscan2
- KIF18B | c.434A>G p.Q145R | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV59271702; called by muse, mutect2
- KLB | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57300654; called by muse, mutect2, varscan2
- KLF6 | c.755G>C p.R252P | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51494080, COSV99434913; called by mutect2, varscan2
- KLHL1 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV64768625; called by muse, mutect2, varscan2
- KLHL1 | c.311A>C p.Q104P | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.046); catalogued as COSV64768630; called by muse, mutect2, varscan2
- KLHL14 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63830724; called by muse, mutect2, varscan2
- KLHL20 | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 202/505 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0.259); catalogued as COSV52940789; called by muse, mutect2, varscan2
- KLHL28 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV61887642; called by muse, mutect2, varscan2
- KLHL4 | c.450G>C p.M150I | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV64140042; called by muse, mutect2, varscan2
- KLHL4 | c.2149C>A p.L717I | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV64140051; called by muse, mutect2, varscan2
- KMT2A | c.4804C>A p.L1602I | Missense Mutation (SNP) | VAF 65/368 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as COSV63283401; called by muse, mutect2, varscan2
- KPRP | c.1489A>T p.S497C | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64221216; called by muse, mutect2, varscan2
- KRT2 | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 211/698 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59009561, COSV59011448; called by muse, mutect2, varscan2
- KRT2 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59009570; called by muse, mutect2
- KRT82 | c.1448C>A p.P483H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV99233775; called by muse, mutect2, varscan2
- KRTAP10-11 | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 136/400 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV58177331; called by muse, mutect2, varscan2
- KRTAP10-8 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as COSV58166066; called by muse, mutect2, varscan2
- KRTAP13-2 | c.198C>G p.C66W | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV67761906; called by muse, mutect2, varscan2
- KRTAP15-1 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 49/303 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV61877159; called by muse, mutect2, varscan2
- LAMP5 | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.446); catalogued as COSV55715465; called by muse, mutect2, varscan2
- LARGE1 | c.2065G>C p.D689H | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as COSV61659215, COSV61668355; called by muse, mutect2, varscan2
- LCK | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV60739086; called by muse, mutect2, varscan2
- LCT | c.2162C>A p.S721* | Nonsense Mutation (SNP) | VAF 44/276 reads (16%) | catalogued as COSV51545713, COSV51552532; called by muse, mutect2, varscan2
- LDB1 | c.230G>T p.R77L (on ENST00000425280 / NM_001321612.2; = p.R41L on NM_003893.5) | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63288832; called by muse, mutect2, varscan2
- LGR5 | c.1751G>A p.R584K | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as COSV57003526; called by muse, mutect2, varscan2
- LIPI | c.977A>G p.K326R | Missense Mutation (SNP) | VAF 32/437 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV60709299; called by muse, mutect2
- LIPI | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 566/881 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as COSV60709310; called by muse, mutect2, varscan2
- LLGL2 | c.2108G>T p.R703L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51344156; called by muse, mutect2, varscan2
- LMOD2 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV71755581; called by muse, mutect2, varscan2
- LRFN5 | c.21T>A p.Y7* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as COSV53247615; called by muse, mutect2, varscan2
- LRP1B | c.1983G>C p.W661C | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67197711; called by muse, mutect2, varscan2
- LRP2 | c.2735A>T p.Q912L | Missense Mutation (SNP) | VAF 217/443 reads (49%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.985); catalogued as COSV55545368; called by muse, mutect2, varscan2
- LRP2 | c.1609A>G p.K537E | Missense Mutation (SNP) | VAF 39/393 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as COSV55545379; called by muse, mutect2, varscan2
- LRRC31 | c.279G>C p.L93F | Missense Mutation (SNP) | VAF 57/648 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52980020; called by muse, mutect2
- LRRC32 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 59/241 reads (24%) | catalogued as COSV52632062, COSV52634683; called by muse, mutect2, varscan2
- LRRC55 | c.341G>C p.R114P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV73006380, COSV73006796, COSV73006817; called by muse, mutect2, varscan2
- LRRC66 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.666); catalogued as COSV58632560; called by muse, mutect2, varscan2
- LRRCC1 | c.2977-2A>G p.X993_splice | Splice Site (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100835245, COSV64482924; called by muse, varscan2
- LTN1 | c.4876-1G>T p.X1626_splice | Splice Site (SNP) | VAF 57/287 reads (20%) | catalogued as COSV63733266; called by muse, mutect2, varscan2
- LVRN | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752119554, COSV63496613; called by muse, mutect2, varscan2
- LYPD6B | c.479G>C p.R160T (on ENST00000409029 / NM_001317004.1; = p.R184T on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/1066 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV54518026; called by muse, mutect2, varscan2
- LYSMD2 | c.368T>C p.L123S | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV51056712; called by muse, mutect2, varscan2
- MAG | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV62699474, COSV62700883; called by muse, mutect2, varscan2
- MAGEA11 | c.226A>T p.S76C | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV60754328; called by muse, mutect2, varscan2
- MAGEB6 | c.1008G>T p.L336F | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV66872026; called by muse, mutect2, varscan2
- MAGEE2 | c.1009C>A p.L337I | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); catalogued as COSV64897464; called by muse, mutect2, varscan2
- MAP3K19 | c.912G>C p.K304N | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV59637313; called by muse, mutect2, varscan2
- MAP3K2 | c.1632C>G p.I544M | Missense Mutation (SNP) | VAF 135/963 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61293432; called by muse, mutect2, varscan2
- MAP3K9 | c.973A>T p.M325L | Missense Mutation (SNP) | VAF 291/686 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV67120436; called by muse, mutect2, varscan2
- MARCHF4 | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV56103662; called by muse, mutect2, varscan2
- MARK1 | c.1610G>C p.G537A | Missense Mutation (SNP) | VAF 47/293 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV65066171; called by muse, mutect2, varscan2
- MASP2 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 146/325 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.213); catalogued as rs779641842, COSV53569337; called by muse, mutect2, varscan2
- MAZ | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs748661675, COSV99361325; called by muse, mutect2, varscan2
- MED12L | c.1254G>T p.Q418H | Missense Mutation (SNP) | VAF 54/437 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56372238; called by muse, mutect2, varscan2
- MEF2D | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs767074542, COSV61727358; called by muse, mutect2, varscan2
- MEFV | c.1724C>G p.S575* | Nonsense Mutation (SNP) | VAF 12/103 reads (12%) | catalogued as COSV54819627, COSV54825044; called by muse, mutect2, varscan2
- MEX3B | c.270A>T p.K90N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61663053; called by muse, mutect2, varscan2
- MFN1 | c.902A>T p.E301V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as COSV54938608; called by mutect2, varscan2
- MFSD8 | c.1094A>T p.Q365L | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); catalogued as COSV56550699; called by muse, mutect2, varscan2
- MIB1 | c.716G>A p.G239D | Missense Mutation (SNP) | VAF 157/827 reads (19%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.986); catalogued as COSV55088709; called by muse, mutect2, varscan2
- MKI67 | c.6988A>T p.K2330* | Nonsense Mutation (SNP) | VAF 226/650 reads (35%) | catalogued as COSV64073232; called by muse, mutect2, varscan2
- MMP16 | c.737A>T p.H246L | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54155557, COSV99687724; called by muse, mutect2, varscan2
- MNAT1 | c.58A>T p.K20* | Nonsense Mutation (SNP) | VAF 30/332 reads (9%) | catalogued as COSV54187905; called by muse, mutect2
- MOB4 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 294/573 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as COSV52095302; called by muse, mutect2, varscan2
- MRPS30 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs751131388, COSV50181565, COSV99138190; called by muse, mutect2, varscan2
- MRPS5 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55533073; called by muse, mutect2, varscan2
- MSH4 | c.1499T>A p.I500K | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV54198560; called by muse, mutect2, varscan2
- MSH4 | c.2048T>A p.M683K | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV54198584; called by muse, mutect2, varscan2
- MTNR1B | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 160/433 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV57065749, COSV99925430; called by muse, mutect2, varscan2
- MTNR1B | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57065762; called by muse, mutect2, varscan2
- MTUS2 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV70914864; called by muse, mutect2, varscan2
- MUC16 | c.42061C>A p.H14021N | Missense Mutation (SNP) | VAF 138/322 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV66690495; called by muse, mutect2, varscan2
- MUC16 | c.15373G>T p.E5125* | Nonsense Mutation (SNP) | VAF 118/302 reads (39%) | catalogued as COSV67453122, COSV67464076; called by muse, mutect2, varscan2
- MUC5B | c.13267G>A p.E4423K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as COSV71590577; called by muse, mutect2, varscan2
- MYCBP2 | c.3876G>T p.W1292C (on ENST00000357337; = p.W1330C on NM_015057.5) | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62012803; called by muse, mutect2, varscan2
- MYH4 | c.1603T>C p.S535P | Missense Mutation (SNP) | VAF 47/339 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55114295; called by muse, mutect2, varscan2
- MYH4 | c.585C>A p.Y195* | Nonsense Mutation (SNP) | VAF 41/117 reads (35%) | catalogued as COSV55114038; called by muse, mutect2, varscan2
- MYLIP | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 35/348 reads (10%) | catalogued as COSV62766489; called by muse, mutect2, varscan2
- MYO18B | c.3540C>G p.I1180M | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV59128727; called by muse, mutect2, varscan2
- MYO3B | c.3490C>T p.H1164Y | Missense Mutation (SNP) | VAF 21/406 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV58697909; called by muse, mutect2
- N4BP2 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs533904341, COSV54700185; called by muse, mutect2, varscan2
- NAALADL1 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60523236; called by muse, mutect2, varscan2
- NABP2 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99907589; called by muse, mutect2, varscan2
- NAV3 | c.989A>T p.K330M | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57067819; called by muse, mutect2, varscan2
- NAV3 | c.1350del p.A451Lfs*41 | Frame Shift Del (DEL) | VAF 44/166 reads (27%) | catalogued as rs35015855; called by mutect2, pindel, varscan2
- NAV3 | c.5618C>A p.T1873N (on ENST00000397909 / NM_001024383.2; = p.T1851N on NM_014903.6) | Missense Mutation (SNP) | VAF 86/283 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as COSV57067838; called by muse, mutect2, varscan2
- NBEA | c.963A>T p.Q321H | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs764919381, COSV59767917; called by muse, mutect2, varscan2
- NBEA | c.8404G>T p.G2802C | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV59767932; called by muse, mutect2, varscan2
- NCAM1 | c.1395C>G p.I465M (on ENST00000316851 / NM_181351.5; = p.I455M on NM_000615.7) | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV57512918; called by muse, mutect2
- NCK2 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as COSV51889337; called by muse, mutect2, varscan2
- NCKAP1L | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV53204580; called by muse, mutect2, varscan2
- NCOA1 | c.841A>G p.R281G | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV56040832; called by muse, mutect2, varscan2
- NCOA6 | c.5234C>T p.S1745F | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1167772569, COSV62862077; called by muse, mutect2, varscan2
- NDST4 | c.2488A>G p.M830V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs752863165, COSV52112404; called by mutect2, varscan2
- NDUFAF7 | c.379A>G p.R127G | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV50017052; called by muse, mutect2, varscan2
- NDUFS8 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV50288094; called by muse, mutect2, varscan2
- NEB | c.2723C>G p.S908C | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV50857815; called by muse, mutect2, varscan2
- NEK9 | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV53129872; called by muse, mutect2
- NELFCD | c.1648A>G p.I550V (on ENST00000602795; = p.I532V on NM_198976.4) | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.972); catalogued as rs1015884580, COSV53882720; called by muse, mutect2, varscan2
- NELL2 | c.1493T>A p.L498* | Nonsense Mutation (SNP) | VAF 176/498 reads (35%) | catalogued as COSV61571201; called by muse, mutect2, varscan2
- NEUROD6 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 73/290 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.913); catalogued as rs777808758, COSV51770617; called by muse, mutect2, varscan2
- NEUROG2 | c.322C>A p.R108S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.199); catalogued as COSV57637021; called by muse, mutect2, varscan2
- NEUROG3 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs140128333, CM115180; called by muse, mutect2, varscan2
- NGDN | c.563G>C p.R188P | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV68142071; called by muse, mutect2, varscan2
- NHEJ1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 129/286 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV59428010; called by muse, mutect2, varscan2
- NKTR | c.3709G>T p.A1237S | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); catalogued as COSV51770299; called by muse, mutect2, varscan2
- NKX2-5 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100234940, COSV61298589; called by mutect2, varscan2
- NLGN1 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 279/570 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.272); catalogued as COSV64324308; called by muse, mutect2, varscan2
- NLRP1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs755043231, COSV52561049; called by muse, mutect2, varscan2
- NLRP14 | c.3216C>G p.H1072Q | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV55065066; called by muse, mutect2, varscan2
- NMT2 | c.95C>G p.T32R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV65381462, COSV65381783; called by muse, mutect2
- NOVA1 | c.805G>C p.G269R | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57473772; called by muse, mutect2, varscan2
- NPSR1 | c.1073A>T p.E358V | Missense Mutation (SNP) | VAF 133/477 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); catalogued as COSV62198081; called by muse, mutect2, varscan2
- NPY2R | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1405446935, COSV61527561; called by muse, mutect2, varscan2
- NR1H4 | c.1276C>T p.L426F (on ENST00000551379 / NM_001206993.2; = p.L412F on NM_005123.4) | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51849822, COSV51850320; called by muse, mutect2, varscan2
- NR2E1 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV64561655, COSV64562372; called by muse, mutect2, varscan2
- NR4A1 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54480581; called by muse, mutect2, varscan2
- NRCAM | c.3052T>A p.L1018I (on ENST00000379028 / NM_001371124.1; = p.L1002I on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV61032925; called by muse, mutect2, varscan2
- NRF1 | c.1185G>T p.E395D | Missense Mutation (SNP) | VAF 93/173 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56210831, COSV56211308; called by muse, mutect2, varscan2
- NRP2 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 58/581 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV55925026; called by muse, mutect2
- NSFL1C | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53792266; called by muse, mutect2, varscan2
- NUCKS1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 19/133 reads (14%) | catalogued as COSV63347811; called by muse, mutect2, varscan2
- NUDCD1 | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 94/743 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as rs1001571910, COSV53454988; called by muse, mutect2, varscan2
- NUP210L | c.2165A>C p.Q722P | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV55143647; called by muse, mutect2, varscan2
- NUP214 | c.2009C>T p.T670I | Missense Mutation (SNP) | VAF 15/385 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV63908292; called by muse, mutect2
- NXPE4 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 85/688 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as COSV64943549; called by muse, mutect2, varscan2
- NYAP2 | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 231/555 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56000773; called by muse, mutect2, varscan2
- OIT3 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV61825442; called by muse, mutect2
- OLAH | c.188G>T p.R63I (on ENST00000378228 / NM_001039702.3; = p.R116I on NM_018324.3) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65491813; called by muse, mutect2, varscan2
- OR10AG1 | c.743T>A p.I248N | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56632076; called by muse, mutect2, varscan2
- OR13C3 | c.441G>T p.M147I | Missense Mutation (SNP) | VAF 386/892 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV66165692, COSV66166418; called by muse, mutect2, varscan2
- OR13G1 | c.177C>A p.F59L | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as COSV62943353, COSV62943685; called by muse, mutect2, varscan2
- OR1L4 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 148/300 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV52339955; called by muse, mutect2, varscan2
- OR1N2 | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 93/343 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV65460366; called by muse, mutect2, varscan2
- OR2M2 | c.124A>T p.N42Y | Missense Mutation (SNP) | VAF 585/1316 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62897972; called by muse, mutect2, varscan2
- OR2T27 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 107/198 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV61281183; called by muse, mutect2, varscan2
- OR2T34 | c.647T>C p.I216T | Missense Mutation (SNP) | VAF 143/790 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs1458126700, COSV60899952; called by muse, mutect2, varscan2
- OR2V2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 130/551 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.674); catalogued as COSV60314628; called by muse, mutect2, varscan2
- OR2V2 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV60314942; called by muse, mutect2, varscan2
- OR2W3 | c.417G>T p.R139S | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as COSV64456332; called by muse, mutect2, varscan2
- OR2Y1 | c.902G>T p.W301L | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV57136268; called by muse, mutect2, varscan2
- OR4E2 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 194/1103 reads (18%) | SIFT tolerated (0.4); PolyPhen probably damaging (1); catalogued as COSV100330130; called by muse, mutect2, varscan2
- OR4M1 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 137/904 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs548222329, COSV100271360; called by muse, mutect2, varscan2
- OR4M2 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 150/700 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV100221254, COSV60306757; called by muse, mutect2, varscan2
- OR4S2 | c.593C>A p.T198K | Missense Mutation (SNP) | VAF 215/755 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV56746211; called by muse, mutect2, varscan2
- OR51B6 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 172/684 reads (25%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.764); catalogued as COSV66512477; called by muse, mutect2, varscan2
- OR51E1 | c.498C>G p.I166M | Missense Mutation (SNP) | VAF 290/1520 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV67809524, COSV67809965; called by muse, varscan2
- OR52L1 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV59986207; called by muse, varscan2
- OR52L1 | c.808T>A p.Y270N | Missense Mutation (SNP) | VAF 64/288 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59986231; called by muse, varscan2
- OR56B4 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 82/418 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV57204178; called by muse, mutect2, varscan2
- OR5B21 | c.476C>A p.A159E | Missense Mutation (SNP) | VAF 65/532 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.288); catalogued as rs907530877, COSV64481686; called by muse, mutect2, varscan2
- OR5B21 | c.39G>C p.L13F | Missense Mutation (SNP) | VAF 49/317 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV64481691; called by muse, mutect2, varscan2
- OR5M1 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 105/460 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73202002; called by muse, mutect2, varscan2
- OR5M3 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as rs1401009743; called by muse, mutect2, varscan2
- OR6C2 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 172/457 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as COSV59515727; called by muse, mutect2, varscan2
- OR6C4 | c.154del p.H52Tfs*16 | Frame Shift Del (DEL) | VAF 61/573 reads (11%) | catalogued as COSV67793392; called by mutect2, pindel, varscan2
- OR6K3 | c.301C>A p.L101I (on ENST00000368146; = p.L85I on NM_001005327.2) | Missense Mutation (SNP) | VAF 140/1205 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV63745407; called by muse, mutect2, varscan2
- OR9K2 | c.245C>A p.T82K (on ENST00000305377; = p.T60K on NM_001005243.1) | Missense Mutation (SNP) | VAF 262/855 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59531553; called by muse, mutect2, varscan2
- OSBPL11 | c.842C>G p.S281* | Nonsense Mutation (SNP) | VAF 67/332 reads (20%) | catalogued as COSV56172947; called by muse, mutect2, varscan2
- OSBPL3 | c.108A>T p.E36D | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57654265; called by muse, mutect2, varscan2
- OSBPL8 | c.431C>G p.T144R | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.05); catalogued as COSV53879671, COSV53889413; called by muse, mutect2
- OTOP1 | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56391653; called by muse, mutect2, varscan2
- PABPC3 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99879732; called by muse, varscan2
- PADI2 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.54); PolyPhen benign (0.041); catalogued as COSV64945455; called by muse, mutect2, varscan2
- PATZ1 | c.1969G>C p.E657Q | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56742999, COSV56743116; called by muse, mutect2
- PAX3 | c.1127C>A p.P376H | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.104); catalogued as COSV60586923; called by muse, mutect2, varscan2
- PAXBP1 | c.1999G>T p.E667* | Nonsense Mutation (SNP) | VAF 92/420 reads (22%) | catalogued as COSV51607563; called by muse, mutect2, varscan2
- PCDH10 | c.1699C>G p.Q567E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV52088403, COSV52089728; called by muse, mutect2, varscan2
- PCDH15 | c.454del p.Y152Tfs*5 | Frame Shift Del (DEL) | VAF 48/301 reads (16%) | catalogued as COSV100217019; called by mutect2, pindel, varscan2
- PCDHA4 | c.2309T>C p.M770T | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV63539736; called by muse, mutect2, varscan2
- PCDHAC1 | c.2402G>A p.R801K | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.017); catalogued as COSV53841059; called by muse, mutect2, varscan2
- PCDHB4 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as COSV52020391, COSV52026805; called by muse, mutect2
- PCDHB5 | c.941A>C p.Y314S | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV50648233, COSV50659224; called by muse, mutect2, varscan2
- PCDHB5 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.932); catalogued as COSV50648249; called by muse, mutect2, varscan2
- PCDHB6 | c.641T>A p.L214Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.643); catalogued as COSV50691738; called by muse, mutect2, varscan2
- PCDHB8 | c.824A>G p.N275S | Missense Mutation (SNP) | VAF 25/467 reads (5%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.574); catalogued as COSV50757227; called by muse, mutect2
- PCDHGA12 | c.994A>G p.K332E | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV52746627; called by muse, mutect2
- PCDHGA6 | c.1159C>G p.P387A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.057); catalogued as COSV53901073, COSV53915353; called by muse, mutect2, varscan2
- PCDHGB3 | c.1844G>T p.G615V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53915342; called by muse, mutect2, varscan2
- PCDHGB6 | c.1202A>T p.Y401F | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV53915374; called by muse, mutect2, varscan2
- PCDHGB6 | c.1396C>G p.P466A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV53915382; called by muse, mutect2, varscan2
- PCID2 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55813171; called by muse, mutect2, varscan2
- PCK1 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs747837917, COSV60126763, COSV60131546; called by muse, mutect2, varscan2
- PCSK2 | c.1372G>C p.D458H | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV52728277; called by muse, mutect2, varscan2
- PCSK4 | c.1417A>G p.R473G | Missense Mutation (SNP) | VAF 5/7 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV56298591, COSV99960865; called by mutect2, varscan2
- PDE1C | c.1976T>A p.L659* | Nonsense Mutation (SNP) | VAF 100/365 reads (27%) | catalogued as COSV58506540; called by muse, mutect2, varscan2
- PDE1C | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 229/948 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs1181737020, COSV58506466; called by muse, mutect2, varscan2
- PDE6A | c.1622C>A p.A541D | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV54925504; called by muse, mutect2, varscan2
- PDE7B | c.1235A>T p.Q412L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV57494329; called by muse, mutect2, varscan2
- PDZD8 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1265351801, COSV53689084; called by muse, mutect2, varscan2
- PGBD2 | c.90G>T p.M30I | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV61399809; called by muse, mutect2, varscan2
- PGK2 | c.305C>G p.A102G | Missense Mutation (SNP) | VAF 179/315 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV59163193; called by muse, mutect2, varscan2
- PHF14 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1419860728, COSV68854645; called by muse, mutect2, varscan2
- PHKA1 | c.3598A>G p.M1200V | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1556200720, COSV59803411; called by muse, varscan2
- PHLDB2 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV67309138; called by muse, mutect2, varscan2
- PIGT | c.1601C>G p.T534S | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54125497; called by muse, mutect2
- PIGZ | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99433910; called by muse, mutect2, varscan2
- PIKFYVE | c.5917G>T p.V1973F | Missense Mutation (SNP) | VAF 80/156 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52238540; called by muse, mutect2, varscan2
- PJA2 | c.806A>T p.Q269L | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV63272162; called by muse, mutect2, varscan2
- PKHD1L1 | c.536T>G p.L179R | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV65739578; called by muse, mutect2, varscan2
- PKHD1L1 | c.3038T>A p.M1013K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV65739583; called by muse, mutect2, varscan2
- PKHD1L1 | c.5438G>A p.S1813N | Missense Mutation (SNP) | VAF 105/374 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.139); catalogued as rs768349010, COSV65739585; called by muse, mutect2, varscan2
- PKHD1L1 | c.10914G>T p.Q3638H | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as COSV65739589; called by muse, mutect2, varscan2
- PKN2 | c.2422A>G p.M808V | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV65142225; called by muse, mutect2, varscan2
- PLAAT5 | c.397G>T p.G133* | Nonsense Mutation (SNP) | VAF 84/303 reads (28%) | catalogued as COSV57136461; called by muse, mutect2, varscan2
- PLAGL2 | c.969G>C p.M323I | Missense Mutation (SNP) | VAF 67/426 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.119); catalogued as COSV55787772; called by muse, mutect2, varscan2
- PLCB1 | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1364886743, COSV62042906; ClinVar: uncertain significance; called by muse, mutect2
- PLCH1 | c.1783A>T p.M595L (on ENST00000340059 / NM_001130960.2; = p.M607L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV58190546; called by muse, mutect2, varscan2
- PLCL1 | c.2855C>T p.P952L | Missense Mutation (SNP) | VAF 433/948 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV70823351; called by muse, mutect2, varscan2
- PLCXD3 | c.774A>C p.K258N | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV60606445; called by muse, mutect2, varscan2
- PLEKHA4 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV54361809; called by muse, varscan2
- PLEKHG2 | c.2560C>T p.Q854* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV52679926; called by mutect2, varscan2
- PLP1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 70/476 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58275871; called by muse, varscan2
- PLS1 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV61833114; called by muse, mutect2, varscan2
- PLXNA2 | c.508G>T p.G170W | Missense Mutation (SNP) | VAF 84/721 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65438532, COSV65443494; called by muse, mutect2, varscan2
- PNKP | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV55586924, COSV55587606; called by muse, mutect2, varscan2
- PNRC2 | c.111G>C p.K37N | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as COSV57623104; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1382A>T p.D461V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV57963555; called by muse, mutect2
- POLR1F | c.252G>C p.E84D | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.87); catalogued as COSV55998005, COSV55998716; called by muse, mutect2, varscan2
- POLR2D | c.229A>T p.R77* | Nonsense Mutation (SNP) | VAF 29/249 reads (12%) | catalogued as COSV55758190; called by muse, mutect2, varscan2
- POLR3B | c.2237A>G p.Y746C | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1228870515, COSV57276841; called by muse, mutect2
- POM121 | c.1417G>A p.D473N (on ENST00000434423; = p.D208N on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs1434954026, COSV57513059; called by muse, mutect2, varscan2
- POM121L12 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV68692478; called by muse, mutect2, varscan2
- POU2F2 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.081); catalogued as COSV60760729; called by muse, mutect2, varscan2
- PPAT | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV51703411; called by muse, mutect2, varscan2
- PPM1F | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV99601606; called by muse, mutect2, varscan2
- PPP1R16B | c.1286G>T p.R429L | Missense Mutation (SNP) | VAF 117/324 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV55375308, COSV55385993; called by muse, mutect2, varscan2
- PPP2R1A | c.986G>T p.C329F | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV59043138; called by muse, mutect2, varscan2
- PRAME | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.131); catalogued as COSV67161208; called by muse, mutect2, varscan2
- PRDM16 | c.2224G>T p.D742Y | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV54583045; called by muse, mutect2, varscan2
- PRDM4 | c.1703A>G p.H568R | Missense Mutation (SNP) | VAF 45/310 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV57304959; called by muse, mutect2, varscan2
- PRDM5 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 56/292 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.037); catalogued as COSV53357408; called by muse, mutect2, varscan2
- PRKCB | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV57770822; called by muse, varscan2
- PRKCI | c.1675G>C p.E559Q | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV55517337; called by muse, mutect2
- PRKD2 | c.1776G>T p.E592D | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52185179, COSV52187662, COSV52188578; called by muse, mutect2, varscan2
- PRNP | c.517A>C p.N173H | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV65173534; called by muse, mutect2, varscan2
- PRSS1 | c.523T>C p.Y175H | Missense Mutation (SNP) | VAF 167/346 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs756821075, COSV61191523; called by muse, mutect2, varscan2
- PSG2 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 206/610 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100283624; called by muse, mutect2, varscan2
- PSG2 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 205/610 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs757071267, COSV100283626; called by muse, mutect2, varscan2
- PTCH1 | c.768G>C p.W256C | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59467038, COSV59467715; called by muse, mutect2, varscan2
- PTGER2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1301996899, COSV99817604; called by muse, mutect2, varscan2
- PTGFRN | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.43); catalogued as COSV67798014; called by muse, mutect2, varscan2
- PTPN14 | c.2641C>T p.R881W | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); catalogued as rs533330548, COSV65282228; called by muse, mutect2, varscan2
- PTPN14 | c.1418A>T p.N473I | Missense Mutation (SNP) | VAF 396/644 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65282232; called by muse, mutect2, varscan2
- PTPRG | c.3307G>A p.V1103I | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1435693144, COSV55632926; called by muse, mutect2, varscan2
- PTPRR | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 51/308 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV51727245; called by muse, mutect2, varscan2
- PTPRU | c.1997G>T p.G666V | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV60523720, COSV60524038; called by muse, mutect2, varscan2
- PTPRZ1 | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV66432680, COSV66446883; called by muse, mutect2, varscan2
- PUM1 | c.2592-2A>C p.X864_splice | Splice Site (SNP) | VAF 53/191 reads (28%) | catalogued as COSV57082951; called by muse, mutect2, varscan2
- PXDN | c.4303A>T p.T1435S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs1212993226, COSV53228955; called by muse, mutect2
- PYGM | c.1828-1G>T p.X610_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV51215319; called by mutect2, varscan2
- QTRT2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 82/807 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV55559228; called by muse, mutect2
- RAB6D | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 53/323 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV72151635; called by muse, mutect2, varscan2
- RAG2 | c.885C>A p.N295K | Missense Mutation (SNP) | VAF 132/590 reads (22%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.764); catalogued as COSV57556844; called by muse, mutect2, varscan2
- RALGAPB | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53435658; called by muse, mutect2, varscan2
- RAP1GDS1 | c.236-2A>T p.X79_splice (on ENST00000408927 / NM_001100427.2; = p.X80_splice on NM_021159.5) | Splice Site (SNP) | VAF 51/135 reads (38%) | catalogued as COSV52785585; called by muse, mutect2, varscan2
- RAPGEF2 | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 156/633 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV52425855; called by muse, mutect2, varscan2
- RBM19 | c.1438A>G p.I480V | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs1247065509, COSV55689339; called by muse, mutect2, varscan2
- RBM39 | c.1291A>G p.M431V (on ENST00000253363 / NM_001323424.2; = p.M425V on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV53614394; called by muse, mutect2, varscan2
- RBM47 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55931723; called by muse, mutect2, varscan2
- RCOR3 | c.459G>T p.Q153H | Missense Mutation (SNP) | VAF 126/1007 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV65365004; called by muse, mutect2, varscan2
- REEP3 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53423630; called by muse, mutect2, varscan2
- RFX1 | c.1851G>A p.E617= | Splice Region (SNP) | VAF 3/11 reads (27%) | catalogued as COSV54328421; called by muse, mutect2
- RHCG | c.1285T>A p.C429S | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV51515086; called by muse, mutect2, varscan2
- RIMS2 | c.2867C>T p.P956L (on ENST00000666250 / NM_001348490.2; = p.P764L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV51662389; called by muse, mutect2, varscan2
- RNF138 | c.108C>G p.H36Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55233605; called by muse, mutect2, varscan2
- RNF213 | c.1285G>C p.D429H | Missense Mutation (SNP) | VAF 52/491 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60620918; called by muse, mutect2, varscan2
- RNF213 | c.14164C>T p.P4722S | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60392763; called by muse, mutect2
- RNF7 | c.57C>G p.S19R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV56421827; called by mutect2, varscan2
- RNGTT | c.252C>G p.I84M | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV55647614; called by muse, mutect2, varscan2
- ROCK1 | c.2676G>T p.L892F | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67694967; called by muse, mutect2, varscan2
- RPIA | c.594C>G p.F198L | Missense Mutation (SNP) | VAF 285/729 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV52168547, COSV52169569; called by muse, mutect2, varscan2
- RPL36A | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); catalogued as COSV100864974; called by muse, mutect2
- RPRD1B | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 58/309 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65032452; called by muse, mutect2, varscan2
- RPRD2 | c.1471A>G p.S491G | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV64819064; called by muse, mutect2, varscan2
- RUNX1 | c.511G>A p.D171N (on ENST00000344691 / NM_001001890.3; = p.D198N on NM_001754.5) | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as CM013280, CM1515470, COSV55868860, COSV55892672; called by muse, mutect2, varscan2
- RYR1 | c.529C>G p.R177G | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM054848, COSV62092259, COSV62108976; called by mutect2, varscan2
- RYR2 | c.3730A>G p.N1244D | Missense Mutation (SNP) | VAF 127/289 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV63671142; called by muse, mutect2, varscan2
- RYR3 | c.7126G>T p.D2376Y (on ENST00000389232; = p.D2377Y on NM_001036.6) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV66781711, COSV66790652; called by muse, varscan2
- S100PBP | c.644C>G p.S215* | Nonsense Mutation (SNP) | VAF 115/328 reads (35%) | catalogued as COSV63139848; called by muse, mutect2, varscan2
- SASH1 | c.1261G>T p.G421C | Missense Mutation (SNP) | VAF 102/227 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV66559780; called by muse, mutect2, varscan2
- SCLY | c.1300G>C p.E434Q (on ENST00000651534; = p.E426Q on NM_016510.7) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV54540577; called by muse, mutect2, varscan2
- SCN1A | c.3892A>C p.S1298R (on ENST00000303395 / NM_001202435.3; = p.S1287R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57663885; called by muse, mutect2, varscan2
- SCN1A | c.126A>T p.K42N | Missense Mutation (SNP) | VAF 378/644 reads (59%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); catalogued as CD105519, COSV57663910; called by muse, mutect2, varscan2
- SCN2A | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 52/438 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV51832124; called by muse, varscan2
- SCN2A | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.472); catalogued as COSV51835615; called by muse, varscan2
- SCOC | c.439A>G p.S147G (on ENST00000608372; = p.S110G on NM_032547.3) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58392702; called by muse, mutect2, varscan2
- SDK2 | c.1411G>T p.G471W | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101168074, COSV101168677; called by muse, mutect2, varscan2
- SDR16C5 | c.809T>G p.L270W | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as COSV100373723, COSV58125799; called by muse, varscan2
- SELP | c.2369C>T p.T790M | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.373); catalogued as rs75278502; called by muse, mutect2
- SEMA3D | c.2177G>C p.S726T | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.056); catalogued as COSV52389632; called by muse, mutect2, varscan2
- SEMG1 | c.433del p.D145Ifs*27 | Frame Shift Del (DEL) | VAF 119/437 reads (27%) | catalogued as COSV54874341; called by mutect2, pindel, varscan2
- SENP7 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 36/285 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV58608272; called by muse, mutect2, varscan2
- SERPINA9 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 79/470 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as COSV100099109, COSV54073583; called by muse, mutect2, varscan2
- SERPINB13 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.926); catalogued as rs369861529; called by muse, mutect2, varscan2
- SETBP1 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 104/345 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV56315918; called by muse, mutect2, varscan2
- SETDB1 | c.3364C>G p.Q1122E | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV54978699; called by muse, mutect2, varscan2
- SH2D2A | c.1154T>G p.L385R | Missense Mutation (SNP) | VAF 218/526 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63884551; called by muse, mutect2
- SH2D2A | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 120/1140 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs992896140, COSV63884570; called by muse, mutect2, varscan2
- SH3BP4 | c.338A>G p.N113S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV60642868; called by muse, mutect2, varscan2
- SH3BP4 | c.2831C>T p.S944F | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs866404069, COSV60642875; called by muse, mutect2, varscan2
- SHPRH | c.2937G>T p.Q979H | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51606173; called by muse, mutect2, varscan2
- SIGLEC12 | c.1780C>A p.P594T (on ENST00000291707 / NM_053003.4; = p.P476T on NM_033329.2) | Missense Mutation (SNP) | VAF 91/461 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as COSV52460154; called by muse, mutect2, varscan2
- SIRT1 | c.892G>C p.D298H | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99281930; called by muse, varscan2
- SKIV2L | c.95T>A p.L32Q | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV64810755; called by muse, mutect2, varscan2
- SLC14A2 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as COSV54907281; called by muse, mutect2, varscan2
- SLC22A6 | c.245C>A p.T82N | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.211); catalogued as rs1353606182, COSV64559950; called by muse, mutect2, varscan2
- SLC24A2 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs377522340; called by muse, mutect2, varscan2
- SLC25A2 | c.68G>A p.C23Y | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV53404421, COSV99508305; called by muse, mutect2
- SLC25A2 | c.67T>A p.C23S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.549); catalogued as COSV99508309; called by muse, mutect2
- SLC25A31 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55418026; called by muse, mutect2, varscan2
- SLC25A53 | c.444A>C p.Q148H | Missense Mutation (SNP) | VAF 115/362 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.382); catalogued as COSV62458557; called by muse, mutect2, varscan2
- SLC26A8 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV62884980; called by muse, mutect2, varscan2
- SLC28A3 | c.1272G>T p.M424I | Missense Mutation (SNP) | VAF 166/379 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV66152360; called by muse, mutect2, varscan2
- SLC32A1 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1473110302, COSV54146028; called by muse, mutect2
- SLC33A1 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63946824; called by muse, mutect2, varscan2
- SLC38A10 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs773661289, COSV55843634; called by muse, mutect2, varscan2
- SLC38A8 | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55305256; called by muse, mutect2, varscan2
- SLC3A1 | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 314/643 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53221537; called by muse, mutect2, varscan2
- SLC3A2 | c.1525G>C p.V509L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV58603031; called by muse, mutect2, varscan2
- SLC45A2 | c.1286G>A p.S429N | Missense Mutation (SNP) | VAF 101/382 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV56870291; called by muse, mutect2, varscan2
- SLC4A1 | c.1042C>G p.Q348E | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52258994; called by muse, varscan2
- SLC4A1 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV52259006; called by muse, varscan2
- SLC4A10 | c.472T>C p.Y158H | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV55769439; called by muse, mutect2, varscan2
- SLC5A7 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50889772; called by muse, mutect2, varscan2
- SLC6A15 | c.146C>A p.T49K | Missense Mutation (SNP) | VAF 66/555 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99881258; called by muse, mutect2, varscan2
- SLC7A6 | c.482C>A p.P161H | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54718128; called by muse, mutect2, varscan2
- SLC9C2 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV100876952, COSV62944522; called by muse, mutect2, varscan2
- SLIT1 | c.1531G>A p.V511M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.083); catalogued as rs748707121, COSV56584912; called by muse, mutect2
- SLITRK4 | c.2488G>C p.E830Q | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV100567439; called by muse, mutect2, varscan2
- SLITRK4 | c.2487G>T p.E829D | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV100567440; called by muse, mutect2, varscan2
- SMARCC2 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV57215288; called by muse, mutect2, varscan2
- SMG1 | c.5997A>G p.K1999= | Splice Region (SNP) | VAF 56/302 reads (19%) | catalogued as COSV67170022; called by muse, mutect2, varscan2
- SMURF2 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1555684658, COSV52313489; called by muse, mutect2, varscan2
- SNAP25 | c.582G>T p.E194D | Missense Mutation (SNP) | VAF 143/538 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV54771199; called by muse, mutect2, varscan2
- SNTG1 | c.350G>T p.R117I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); catalogued as COSV52431693; called by mutect2, varscan2
- SNX27 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV64325848; called by muse, mutect2
- SNX9 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | catalogued as COSV67583544; called by muse, mutect2, varscan2
- SOS1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV67674316; called by muse, mutect2, varscan2
- SPACA3 | c.582-1G>T p.X194_splice | Splice Site (SNP) | VAF 178/535 reads (33%) | catalogued as COSV52190659; called by muse, mutect2, varscan2
- SPAG5 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58800810; called by muse, mutect2, varscan2
- SPEF2 | c.929G>C p.R310T | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV56795442; called by muse, mutect2, varscan2
- SPEF2 | c.4217G>T p.S1406I | Missense Mutation (SNP) | VAF 81/423 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57427953; called by muse, mutect2, varscan2
- SPZ1 | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 136/542 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as COSV57062649; called by muse, mutect2
- SRCAP | c.3169G>T p.G1057W | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99350766; called by muse, mutect2, varscan2
- SRCAP | c.3170G>T p.G1057V | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99350767; called by muse, mutect2, varscan2
- SRGAP1 | c.3017C>T p.T1006M | Missense Mutation (SNP) | VAF 97/264 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.439); catalogued as rs549866334, COSV61895544; called by muse, mutect2, varscan2
- SRGAP3 | c.889del p.E297Kfs*75 | Frame Shift Del (DEL) | VAF 140/633 reads (22%) | catalogued as COSV64533554; called by mutect2, pindel, varscan2
- ST8SIA3 | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | PolyPhen benign (0.022); catalogued as rs1363377732, COSV60653609; called by muse, mutect2, varscan2
- SUOX | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as CD052509, COSV56267315; called by muse, mutect2
- SUSD6 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1212049077, COSV61364839; called by muse, mutect2, varscan2
- SYT11 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 64/617 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.62); catalogued as COSV64173846; called by muse, mutect2
- TANGO6 | c.1775G>T p.G592V | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55762112; called by muse, mutect2, varscan2
- TAP2 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV66487631; called by muse, mutect2, varscan2
- TARS2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV64694796; called by muse, mutect2, varscan2
- TAX1BP1 | c.456G>A p.L152= | Splice Region (SNP) | VAF 6/29 reads (21%) | catalogued as COSV55291388; called by muse, mutect2, varscan2
- TBC1D31 | c.881A>C p.Q294P | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as COSV54864579; called by muse, mutect2, varscan2
- TBC1D8B | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 151/542 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52176900; called by muse, mutect2, varscan2
- TBL1XR1 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV61789771; called by muse, mutect2
- TBX21 | c.1344C>A p.F448L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV51595306; called by muse, mutect2, varscan2
- TCEA2 | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58657383, COSV58659720; called by muse, mutect2
- TCHH | c.1996G>C p.E666Q | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV64273642; called by muse, mutect2, varscan2
- TCHHL1 | c.2231C>A p.S744* | Nonsense Mutation (SNP) | VAF 60/475 reads (13%) | catalogued as COSV64285146; called by muse, mutect2, varscan2
- TCHHL1 | c.883A>G p.R295G | Missense Mutation (SNP) | VAF 406/748 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64285151; called by muse, mutect2, varscan2
- TCOF1 | c.567G>A p.G189= | Splice Region (SNP) | VAF 8/51 reads (16%) | catalogued as COSV60346784; called by muse, mutect2, varscan2
- TDGF1 | c.36-1G>C p.X12_splice | Splice Site (SNP) | VAF 42/234 reads (18%) | catalogued as COSV56125359; called by muse, mutect2, varscan2
- TDRD3 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV52154295; called by muse, mutect2, varscan2
- TENM4 | c.4835A>G p.Y1612C | Missense Mutation (SNP) | VAF 81/507 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53615662; called by muse, mutect2, varscan2
- TEP1 | c.3841G>T p.D1281Y | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52989591; called by muse, mutect2, varscan2
- TET1 | c.4219A>G p.T1407A | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV65383034, COSV65390518; called by muse, mutect2, varscan2
- THBS2 | c.1916C>A p.A639D | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64677629; called by muse, mutect2, varscan2
- THNSL2 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV59082272; called by muse, mutect2, varscan2
- THSD7A | c.3763G>T p.D1255Y | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69855537; called by muse, mutect2
- THSD7A | c.3049A>T p.R1017* | Nonsense Mutation (SNP) | VAF 358/1094 reads (33%) | catalogued as COSV70261914; called by muse, mutect2, varscan2
- THSD7B | c.2142G>A p.M714I | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV55664601; called by muse, mutect2, varscan2
476 further variants in this file (174 protein-altering or splice-affecting, 271 silent, 31 other) are not listed here.
